Somatic mutation profile of tumor specimen TCGA-DU-6404-01A (aliquot TCGA-DU-6404-01A-11D-1705-08) from TCGA case TCGA-DU-6404, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 24.7 years (9,021 days).
Specimen TCGA-DU-6404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f65b771-36ec-4f1f-93ac-7a50972fa0f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6404-10A (Blood Derived Normal), aliquot TCGA-DU-6404-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cb8018e-73f2-45dc-a3e0-229753d250cf

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX3 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as rs142042116; called by muse, mutect2, varscan2
- ATG5 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as COSV58346260; called by muse, mutect2, varscan2
- FPR1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs145808420; called by muse, mutect2, varscan2
- G6PD | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1557230050, COSV63702853; called by muse, mutect2
- GDPD2 | c.1338C>A p.N446K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV65532582; called by muse, mutect2
- KALRN | c.1428A>C p.K476N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53759912; called by muse, mutect2, varscan2
- MAGI3 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs758803760, COSV56833034; called by muse, mutect2, varscan2
- SPP1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as rs757338944, COSV52951625; called by muse, mutect2, varscan2
- TRO | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs377101973, COSV51500058; called by muse, mutect2, varscan2
- CTSG | c.537C>T p.Y179= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs1476151995, COSV53535132; called by muse, mutect2, varscan2
- FMNL2 | c.1308C>T p.V436= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs749090031, COSV56492901; called by muse, mutect2, varscan2
- SLC25A19 | c.246C>T p.H82= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs535476833, COSV57467410; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SSU72P8 | c.552A>G p.G184= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
